Somatic mutation profile of tumor specimen 0DSTYC from CCDI case PBCIPP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.4 years (893 days).
Specimen 0DSTYC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 538947a8-d882-4368-8042-67f66fd45986.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSTY7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8a636ea-d752-42c1-ab4b-6341237d56ab

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 2, Silent 1, Frame Shift Del 1, 3'UTR 1, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC126283.2 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 273/1082 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1350193194, COSV67098235; called by muse, mutect2, varscan2
- CASKIN1 | c.2462G>A p.R821H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1425749978; called by muse, varscan2
- PPP1R14B | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.133); catalogued as rs750523503, COSV54185926; called by muse, varscan2
- STK38 | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 153/676 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as COSV57708906; called by muse, mutect2, varscan2
- ADH7 | c.1097A>T p.K366I | Missense Mutation (SNP) | VAF 142/1029 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- DIP2C | c.2468A>G p.Y823C | Missense Mutation (SNP) | VAF 91/191 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MCM3AP | c.2447A>G p.N816S | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- NPAS3 | c.2130del p.I711Ffs*99 (on ENST00000356141 / NM_001164749.2; = p.I679Ffs*99 on NM_022123.3) | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- NRAP | c.695A>C p.Y232S | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- PLXNB3 | c.3175_3177dup p.Q1059dup | In Frame Ins (INS) | VAF 2/16 reads (13%) | called by mutect2, varscan2
- PRKCG | c.1171G>C p.D391H | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RNF168 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 96/442 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- ZNF761 | c.184G>C p.A62P | Missense Mutation (SNP) | VAF 61/557 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- OR10X1 | c.42C>T p.D14= | Silent (SNP) | VAF 50/1008 reads (5%) | called by muse, mutect2
- C2CD3 | c.1843+85T>C | Intron (SNP) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- GPRC5B | chr16:19885643 del C | 5'Flank (DEL) | VAF 2/12 reads (17%) | called by mutect2, varscan2
- RAB40C | c.*60C>A | 3'UTR (SNP) | VAF 3/15 reads (20%) | called by muse, varscan2
- STAG3 | c.2221-79C>T | Intron (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100425926; called by mutect2, varscan2
